National Lung Screening Trial (NLST) participant 112214 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 72 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 22, study year T0. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: left lower lobe. Histology: large cell carcinoma, NOS (ICD-O-3 8012/3). Grade: poorly differentiated (G3). Tumour size on pathology: 100 mm. AJCC 6th edition staging: stage IB (best stage, from pathologic TNM); clinical T2 N0 M0 (stage IB); pathologic T2 N0 M0 (stage IB). AJCC 7th edition staging: stage IIB; clinical T3 N0 M0; pathologic T3 N0 M0.
